Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YO, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YO-01A (Primary Tumor).

Patient: [REDACTED]

Surgical Pathology: Final [REDACTED] Acc# [REDACTED]

Surg Path

CLINICAL HISTORY:

Seizures. Tumor.

GROSS EXAMINATION:

A. "Biopsy brain tumor (Afl)", in formalin. The specimen is several fragments of pink-tan to brown tissue measuring 1 x 0.8 x 0.8 cm in aggregate dimension. A portion of the specimen has been previously submitted as frozen section Afl. Frozen section remnant is submitted in Block A1 and the remaining tissue is submitted in Block A2.

B. "Brain tumor", in formalin. The specimen is multiple fragments of white to gray-tan tissue measuring 5 x 4 x 1.8 cm in aggregate dimension. A small amount of the tissue is retained in formalin and the remaining tissue is sectioned and submitted in toto in Blocks R1-RR

INTRA OPERATIVE CONSULTATION:

A. "Biopsy brain tumor": Afl- glioma, high grade probable oligodendroglioma

MICROSCOPIC EXAMINATION:

Tissue submitted as "brain tumor" consists of portions of brain which are infiltrated by a neoplastic proliferation of malignant oligodendroglial cells. Focally cells with hyperchromatic, irregularly lobulated nuclei are seen within areas with tightly packed tumor cells. Tumor degeneration associated with hemorrhages are present. There is no evidence of vascular proliferation. There is no evidence of pseudopalisading about the areas of necrosis.

DIAGNOSIS:

A. "BIOPSY, BRAIN TUMOR":

ANAPLASTIC OLIGODENDROGLIOMA.

B. "BRAIN TUMOR":

ANAPLASTIC OLIGODENDROGLIOMA.

Verified by: [REDACTED]

Date Signed: [REDACTED]

ICD O-3
Oligodendroglioma, grade III 9451/3
Date: 4/30/13
path
Brain NOS
C71.0
C71.9
9/25/14

HI/PA Discrepancy		

Source: NCI Genomic Data Commons file 74c5baa7-3183-479b-a74b-a079b82204f5 (TCGA-E1-A7YO.3A005836-F7CF-4423-8548-06C956BC96B9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).